Somatic mutation profile of tumor specimen MMRF_2787_1_BM_CD138pos (aliquot MMRF_2787_1_BM_CD138pos_T1_KHS5U_L15730) from MMRF case MMRF_2787, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.4 years (19,501 days).
Specimen MMRF_2787_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 447c195e-eb51-43bf-8a06-4e184da54025.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2787_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2787_1_PB_WBC_C3_KHS5U_L15774; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1059a5e-ef0c-4a08-89f4-be61751ceaf6

The open-access MAF lists 189 somatic variants for this specimen: 63 protein-altering or splice-affecting, 22 silent, 104 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 49, Missense Mutation 48, Intron 24, Silent 22, 5'UTR 13, 5'Flank 8, Splice Site 8, 3'Flank 6, RNA 4, Nonsense Mutation 3, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 24/48 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ADD2 | c.1133G>T p.R378I | Missense Mutation (SNP) | VAF 125/255 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52456474; called by muse, mutect2, varscan2
- ARHGAP17 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as rs1368475804; called by muse, mutect2, varscan2
- FBXO9 | c.1082_1083+1del | In Frame Del (DEL) | VAF 38/46 reads (83%) | catalogued as rs1405583466; called by pindel, varscan2
- FTMT | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs945202730; called by muse, mutect2, varscan2
- H3C10 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 107/213 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.139); catalogued as rs927346584; called by muse, mutect2, varscan2
- HDAC4 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 114/251 reads (45%) | catalogued as rs1336002481, COSV61868169; called by muse, mutect2, varscan2
- IGHV2-70 | c.121T>C p.C41R | Missense Mutation (SNP) | VAF 66/72 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373749501; called by muse, varscan2
- IGLV3-1 | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.662); catalogued as rs189772470; called by muse, varscan2
- KIRREL3 | c.1696+4C>T | Splice Region (SNP) | VAF 181/393 reads (46%) | catalogued as rs768499290, COSV69385112; called by muse, mutect2, varscan2
- LRRC8D | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 102/229 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV100487031; called by muse, mutect2, varscan2
- MTMR1 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 90/92 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100953141; called by muse, mutect2, varscan2
- MYO1E | c.3+1G>A p.X1_splice | Splice Site (SNP) | VAF 36/69 reads (52%) | catalogued as rs543195936; called by muse, mutect2, varscan2
- OR5D14 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.084); catalogued as rs780328529; called by muse, mutect2
- RPAP3 | c.1586A>C p.E529A | Missense Mutation (SNP) | VAF 42/421 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as rs1349506887; called by muse, mutect2
- RRAGA | c.707A>C p.K236T | Missense Mutation (SNP) | VAF 116/252 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65843170; called by muse, mutect2, varscan2
- SFXN5 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs371438584; called by muse, mutect2, varscan2
- SPTBN2 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs534424012; called by muse, mutect2, varscan2
- UNC5D | c.2088T>G p.F696L | Missense Mutation (SNP) | VAF 201/427 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54792067; called by muse, mutect2, varscan2
- VEPH1 | c.2175G>T p.E725D | Missense Mutation (SNP) | VAF 85/197 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62881157; called by muse, mutect2, varscan2
- AC087491.1 | n.159+2T>G | Splice Site (SNP) | VAF 73/391 reads (19%) | called by muse, mutect2, varscan2
- ACTRT3 | c.1114T>G p.F372V | Missense Mutation (SNP) | VAF 75/158 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAP1 | c.398A>C p.E133A | Missense Mutation (SNP) | VAF 68/136 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, varscan2
- AGO4 | c.2150T>G p.L717R | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANO3 | c.214T>G p.L72V | Missense Mutation (SNP) | VAF 94/190 reads (49%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- BIRC6 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 85/193 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CDHR2 | c.3207-2A>G p.X1069_splice | Splice Site (SNP) | VAF 64/146 reads (44%) | called by muse, mutect2, varscan2
- CFAP47 | c.5221T>G p.S1741A | Missense Mutation (SNP) | VAF 65/68 reads (96%) | SIFT tolerated (0.63); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- CYRIB | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 45/99 reads (45%) | called by muse, mutect2, varscan2
- DHX58 | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 11/312 reads (4%) | SIFT tolerated (0.96); PolyPhen benign (0.005); called by muse, mutect2
- GADD45B | c.14_15del p.E5Afs*57 | Frame Shift Del (DEL) | VAF 80/219 reads (37%) | called by pindel, varscan2
- GAS7 | c.515A>T p.N172I (on ENST00000432992 / NM_201433.2; = p.N32I on NM_003644.3) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPR137B | c.47T>A p.M16K | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, varscan2
- GPR149 | c.1584G>C p.W528C | Missense Mutation (SNP) | VAF 161/350 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- H1-4 | c.314T>G p.F105C | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGLV3-1 | c.204_209delinsGAGAAC p.D69_S70delinsRT | Missense Mutation (ONP) | VAF 53/142 reads (37%) | called by pindel, varscan2*
- IKZF1 | c.419_421+2delinsA p.X140_splice | Splice Site (DEL) | VAF 12/74 reads (16%) | called by pindel, varscan2*
- KLHL6 | c.50A>C p.E17A | Missense Mutation (SNP) | VAF 113/276 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- MACF1 | c.2549G>A p.G850E | Missense Mutation (SNP) | VAF 79/189 reads (42%) | called by muse, mutect2, varscan2
- MSMO1 | c.512A>T p.K171I | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH13 | c.2210G>A p.G737E | Missense Mutation (SNP) | VAF 81/160 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MYO5C | c.4127A>C p.Q1376P | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- NHLRC4 | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 89/208 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- NOSTRIN | c.815C>A p.S272Y (on ENST00000317647 / NM_001039724.4; = p.S194Y on NM_052946.3) | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- NRXN1 | c.4039-2A>T p.X1347_splice | Splice Site (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- OR8H1 | c.782C>G p.P261R | Missense Mutation (SNP) | VAF 102/202 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCLO | c.2480A>C p.D827A | Missense Mutation (SNP) | VAF 110/253 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- PLIN3 | c.782C>T p.T261I | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PPP1R9A | c.1621G>C p.E541Q | Missense Mutation (SNP) | VAF 113/304 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- RBPJ | c.409A>T p.K137* | Nonsense Mutation (SNP) | VAF 124/231 reads (54%) | called by muse, mutect2, varscan2
- RUBCN | c.1790C>A p.A597D | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- S100A9 | c.273C>A p.H91Q | Missense Mutation (SNP) | VAF 98/208 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA6D | c.1076A>G p.E359G | Missense Mutation (SNP) | VAF 106/247 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SH3GL2 | c.187+2T>C p.X63_splice | Splice Site (SNP) | VAF 105/221 reads (48%) | called by muse, mutect2, varscan2
- SPAST | c.260T>G p.M87R | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- STAMBP | c.244T>C p.S82P | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- TMEM43 | c.584-1G>A p.X195_splice | Splice Site (SNP) | VAF 121/288 reads (42%) | called by muse, mutect2, varscan2
- TRHDE | c.1242dup p.V415Cfs*27 | Frame Shift Ins (INS) | VAF 40/138 reads (29%) | called by mutect2, pindel, varscan2
- TRIM29 | c.1309A>T p.I437F | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- TTC21B | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2
- TTC34 | c.2719G>A p.A907T | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF286A | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 23/414 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- ZNF385D | c.165+2T>C p.X55_splice | Splice Site (SNP) | VAF 86/197 reads (44%) | called by muse, mutect2, varscan2
- C6orf120 | c.124C>T p.L42= | Silent (SNP) | VAF 61/65 reads (94%) | catalogued as rs377523211; called by muse, mutect2, varscan2
- CFAP65 | c.1038G>A p.V346= | Silent (SNP) | VAF 51/276 reads (18%) | catalogued as rs755254872; called by muse, mutect2, varscan2
- DOP1B | c.5832T>C p.N1944= | Silent (SNP) | VAF 183/346 reads (53%) | called by muse, mutect2, varscan2
- FAM20C | c.609G>A p.P203= | Silent (SNP) | VAF 81/87 reads (93%) | catalogued as rs752027836, COSV58234270; called by muse, mutect2, varscan2
- FAM98A | c.807G>A p.L269= | Silent (SNP) | VAF 94/207 reads (45%) | called by muse, mutect2, varscan2
- GOLGA2 | c.606G>A p.E202= | Silent (SNP) | VAF 161/320 reads (50%) | called by muse, mutect2, varscan2
- H2AC11 | c.345G>A p.V115= | Silent (SNP) | VAF 231/449 reads (51%) | catalogued as rs561275841; called by muse, mutect2, varscan2
- H2AC8 | c.348G>A p.L116= | Silent (SNP) | VAF 141/308 reads (46%) | catalogued as rs1433442309; called by muse, mutect2, varscan2
- IGHMBP2 | c.2856C>T p.A952= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs759627672, COSV99662401; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- IGKC | c.285C>T p.S95= | Silent (SNP) | VAF 91/234 reads (39%) | catalogued as rs3210130; called by muse, mutect2, varscan2
- KCNB1 | c.1236C>T p.I412= | Silent (SNP) | VAF 94/200 reads (47%) | catalogued as rs777806517, COSV65569418; called by muse, mutect2, varscan2
- MAP3K9 | c.1809G>A p.T603= | Silent (SNP) | VAF 64/142 reads (45%) | catalogued as rs1291895055; called by muse, varscan2
- MOGAT3 | c.651C>T p.R217= | Silent (SNP) | VAF 94/182 reads (52%) | called by muse, mutect2, varscan2
- MSMO1 | c.513A>G p.K171= | Silent (SNP) | VAF 40/89 reads (45%) | called by muse, mutect2, varscan2
- NAT9 | c.7T>C p.L3= | Silent (SNP) | VAF 101/238 reads (42%) | catalogued as COSV100120729; called by muse, mutect2, varscan2
- NAV3 | c.1578T>A p.G526= | Silent (SNP) | VAF 169/276 reads (61%) | called by muse, mutect2, varscan2
- NAV3 | c.4020A>G p.T1340= | Silent (SNP) | VAF 98/157 reads (62%) | called by muse, mutect2, varscan2
- OXCT2 | c.840G>A p.E280= | Silent (SNP) | VAF 128/325 reads (39%) | called by muse, mutect2, varscan2
- SHKBP1 | c.1749C>T p.D583= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs779030747; called by muse, mutect2, varscan2
- TTLL12 | c.1773C>T p.N591= | Silent (SNP) | VAF 57/122 reads (47%) | catalogued as rs34490661; called by muse, mutect2, varscan2
- TTN | c.28143C>T p.L9381= (on ENST00000591111; = p.L8454= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 82/206 reads (40%) | catalogued as rs763143292, COSV100627703; called by muse, mutect2, varscan2
- ZNF783 | c.168G>A p.K56= | Silent (SNP) | VAF 16/308 reads (5%) | called by muse, mutect2
- ABCC9 | c.406+961T>A | Intron (SNP) | VAF 63/101 reads (62%) | called by muse, mutect2, varscan2
- ADH6 | chr4:99203429 T>C | 3'Flank (SNP) | VAF 51/107 reads (48%) | called by muse, mutect2, varscan2
- AFF4 | c.*4784T>G | 3'UTR (SNP) | VAF 40/89 reads (45%) | called by muse, mutect2, varscan2
- AFF4 | c.*4541T>G | 3'UTR (SNP) | VAF 52/100 reads (52%) | called by muse, mutect2, varscan2
- ANKH | c.*303_*305del | 3'UTR (DEL) | VAF 65/151 reads (43%) | called by pindel, varscan2
- AP000812.4 | c.*1461C>T | 3'UTR (SNP) | VAF 51/107 reads (48%) | called by muse, mutect2, varscan2
- AP3S2 | c.*3749G>C | 3'UTR (SNP) | VAF 73/160 reads (46%) | called by muse, mutect2, varscan2
- APBA1 | c.*1079C>T | 3'UTR (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- APBB2 | c.*677G>A | 3'UTR (SNP) | VAF 52/117 reads (44%) | catalogued as rs576190551; called by muse, mutect2, varscan2
- BCL7A | chr12:122021146 A>T | 5'Flank (SNP) | VAF 64/182 reads (35%) | called by muse, varscan2
- BCL7A | chr12:122021307 A>C | 5'Flank (SNP) | VAF 86/132 reads (65%) | catalogued as rs369011567; called by muse, varscan2
- BCL7A | chr12:122021360 A>G | 5'Flank (SNP) | VAF 50/161 reads (31%) | called by muse, varscan2
- BCL7A | chr12:122021524 G>C | 5'Flank (SNP) | VAF 148/240 reads (62%) | catalogued as COSV55848044; called by muse, mutect2, varscan2
- BCL7A | c.-3A>G | 5'UTR (SNP) | VAF 49/81 reads (60%) | catalogued as rs1312995047; called by muse, mutect2, varscan2
- BMPR1B | chr4:95155233 C>T | 3'Flank (SNP) | VAF 9/139 reads (6%) | called by muse, mutect2
- C16orf95 | c.-36T>A | 5'UTR (SNP) | VAF 54/162 reads (33%) | called by muse, mutect2
- CACNA2D1 | chr7:81947823 C>G | 3'Flank (SNP) | VAF 58/110 reads (53%) | called by muse, mutect2, varscan2
- CCDC40 | c.2619+70C>G | Intron (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- CCND3 | c.198+253G>A | Intron (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- CDK20 | c.688-33C>A | Intron (SNP) | VAF 178/366 reads (49%) | called by muse, mutect2, varscan2
- CEP57 | c.885+615G>A | Intron (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- CGNL1 | c.*1886G>A | 3'UTR (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- CLIC5 | c.*508G>T | 3'UTR (SNP) | VAF 76/85 reads (89%) | called by muse, mutect2, varscan2
- CLMN | c.*2351T>C | 3'UTR (SNP) | VAF 61/101 reads (60%) | called by muse, mutect2, varscan2
- COPG2 | c.*113C>A | 3'UTR (SNP) | VAF 6/73 reads (8%) | catalogued as rs1554440042; called by muse, mutect2
- CRACDL | c.*131G>A | 3'UTR (SNP) | VAF 41/75 reads (55%) | called by muse, mutect2, varscan2
- CRYM | c.674-92G>A | Intron (SNP) | VAF 8/78 reads (10%) | catalogued as rs1199976313; called by muse, mutect2, varscan2
- DAB1 | c.597+12A>G | Intron (SNP) | VAF 110/214 reads (51%) | called by muse, mutect2, varscan2
- DHX40P1 | n.968T>A | RNA (SNP) | VAF 115/242 reads (48%) | called by muse, mutect2, varscan2
- DIP2B | c.*1234G>C | 3'UTR (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- DPP10 | c.*3377A>G | 3'UTR (SNP) | VAF 17/46 reads (37%) | catalogued as rs1049024749; called by muse, mutect2, varscan2
- DTX1 | c.-502_-500del | 5'UTR (DEL) | VAF 18/23 reads (78%) | called by pindel, varscan2
- DTX1 | c.-425G>C | 5'UTR (SNP) | VAF 39/58 reads (67%) | called by muse, varscan2
- EPB41L1 | c.1669-3076C>T | Intron (SNP) | VAF 149/338 reads (44%) | catalogued as rs1394228440; called by muse, mutect2, varscan2
- ETS1 | chr11:128459957 A>G | 3'Flank (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2, varscan2
- FAM126A | c.*464A>G | 3'UTR (SNP) | VAF 48/107 reads (45%) | called by muse, mutect2, varscan2
- FAM204A | chr10:118307787 T>C | 3'Flank (SNP) | VAF 51/93 reads (55%) | called by muse, mutect2, varscan2
- FBXO41 | c.*3313G>A | 3'UTR (SNP) | VAF 88/197 reads (45%) | catalogued as rs1022226109; called by muse, mutect2, varscan2
- GABPB2 | c.*6409G>C | 3'UTR (SNP) | VAF 49/138 reads (36%) | called by muse, mutect2, varscan2
- GHRHR | c.-36C>T | 5'UTR (SNP) | VAF 57/121 reads (47%) | called by muse, mutect2, varscan2
- GOLT1A | c.*18C>A | 3'UTR (SNP) | VAF 150/348 reads (43%) | called by muse, mutect2, varscan2
- GPLD1 | c.-60A>G | 5'UTR (SNP) | VAF 113/218 reads (52%) | called by muse, mutect2, varscan2
- GPR137B | c.-5C>G | 5'UTR (SNP) | VAF 22/40 reads (55%) | called by muse, varscan2
- GRPEL2 | c.*931T>C | 3'UTR (SNP) | VAF 56/111 reads (50%) | called by muse, mutect2, varscan2
- GULP1 | c.843+1465A>T | Intron (SNP) | VAF 43/97 reads (44%) | called by muse, mutect2, varscan2
- HNMT | c.190+11390A>T | Intron (SNP) | VAF 28/90 reads (31%) | called by muse, mutect2, varscan2
- HTR2C | c.349+31644C>T | Intron (SNP) | VAF 109/112 reads (97%) | catalogued as rs781866646, COSV99348909; called by muse, mutect2, varscan2
- IGF2BP1 | c.*3448T>A | 3'UTR (SNP) | VAF 66/148 reads (45%) | called by muse, mutect2
- IGLL5 | c.-21T>A | 5'UTR (SNP) | VAF 66/136 reads (49%) | catalogued as COSV73250407; called by muse, mutect2, varscan2
- IGLON5 | c.*610C>T | 3'UTR (SNP) | VAF 75/156 reads (48%) | called by muse, mutect2, varscan2
- KCNN3 | c.*429T>G | 3'UTR (SNP) | VAF 74/167 reads (44%) | called by muse, mutect2, varscan2
- LINC01159 | chr2:104872457 A>G | 5'Flank (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- LRBA | c.7726+739G>A | Intron (SNP) | VAF 38/94 reads (40%) | called by muse, mutect2, varscan2
- LTB | c.209-79C>G | Intron (SNP) | VAF 73/148 reads (49%) | called by muse, mutect2, varscan2
- LTB | c.163-144C>T | Intron (SNP) | VAF 141/304 reads (46%) | catalogued as rs534971843; called by muse, mutect2, varscan2
- LTBP4 | c.342-147C>T | Intron (SNP) | VAF 23/36 reads (64%) | called by muse, mutect2, varscan2
- MLIP | c.1113+13401T>A | Intron (SNP) | VAF 35/38 reads (92%) | called by muse, mutect2, varscan2
- MLLT3 | c.1125+2560A>T | Intron (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- MPPED2 | c.*3484G>C | 3'UTR (SNP) | VAF 45/102 reads (44%) | called by muse, mutect2, varscan2
- MYO10 | c.21+19654G>T | Intron (SNP) | VAF 172/372 reads (46%) | called by muse, mutect2, varscan2
- MYO1E | c.-177A>C | 5'UTR (SNP) | VAF 67/140 reads (48%) | called by muse, varscan2
- MYO1E | c.-229A>T | 5'UTR (SNP) | VAF 85/184 reads (46%) | called by muse, varscan2
- MYSM1 | c.*2428T>G | 3'UTR (SNP) | VAF 16/146 reads (11%) | called by muse, mutect2, varscan2
- NAPA | c.296-1263T>A | Intron (SNP) | VAF 51/110 reads (46%) | called by muse, mutect2, varscan2
- NCDN | c.*674G>A | 3'UTR (SNP) | VAF 122/265 reads (46%) | called by muse, mutect2, varscan2
- NFIA | c.*1921A>C | 3'UTR (SNP) | VAF 62/118 reads (53%) | called by muse, mutect2, varscan2
- NKX2-8 | c.-157G>T | 5'UTR (SNP) | VAF 62/137 reads (45%) | called by muse, mutect2, varscan2
- NLGN1 | c.*1865C>T | 3'UTR (SNP) | VAF 44/90 reads (49%) | called by muse, mutect2, varscan2
- NPHS2 | chr1:179575950 G>A | 5'Flank (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- OR4C10P | n.404A>C | RNA (SNP) | VAF 140/293 reads (48%) | called by muse, mutect2, varscan2
- OR52E5 | c.*197C>G | 3'UTR (SNP) | VAF 11/133 reads (8%) | called by muse, mutect2
- PCDH7 | c.*10T>G | 3'UTR (SNP) | VAF 211/439 reads (48%) | called by muse, mutect2, varscan2
- PGRMC1 | c.*457A>C | 3'UTR (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- PHF21B | c.*207G>A | 3'UTR (SNP) | VAF 22/191 reads (12%) | catalogued as rs1032381795; called by muse, mutect2, varscan2
- PLIN4 | c.*1826G>A | 3'UTR (SNP) | VAF 22/240 reads (9%) | catalogued as rs991617247; called by muse, mutect2
- PNRC2 | c.*1284T>A | 3'UTR (SNP) | VAF 119/296 reads (40%) | called by muse, mutect2, varscan2
- PNRC2 | c.*1450T>G | 3'UTR (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- PRAMEF1 | c.*557C>T | 3'UTR (SNP) | VAF 145/307 reads (47%) | catalogued as rs1450153250; called by muse, mutect2, varscan2
- PRRX1 | c.*339A>C | 3'UTR (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- PSMC5 | c.25-174A>G | Intron (SNP) | VAF 43/90 reads (48%) | called by muse, mutect2, varscan2
- RIMS4 | c.*2442A>G | 3'UTR (SNP) | VAF 148/317 reads (47%) | called by muse, mutect2, varscan2
- RITA1 | c.-270G>A | 5'UTR (SNP) | VAF 79/122 reads (65%) | called by muse, mutect2, varscan2
- RSF1 | c.*798_*799del | 3'UTR (DEL) | VAF 54/164 reads (33%) | called by pindel, varscan2
- RTL6 | c.*877C>T | 3'UTR (SNP) | VAF 88/181 reads (49%) | called by muse, mutect2
- SDC1 | c.*729A>C | 3'UTR (SNP) | VAF 63/149 reads (42%) | called by muse, mutect2, varscan2
- SDHA | c.1065-37G>A | Intron (SNP) | VAF 118/255 reads (46%) | catalogued as rs201995189; called by muse, mutect2, varscan2
- SFTA3 | n.763C>T | RNA (SNP) | VAF 43/94 reads (46%) | called by muse, mutect2, varscan2
- SGIP1 | c.*1774T>C | 3'UTR (SNP) | VAF 46/88 reads (52%) | called by muse, mutect2, varscan2
- SH3BP2 | c.429-157G>A | Intron (SNP) | VAF 51/109 reads (47%) | called by muse, mutect2
- SLC37A2 | c.*660C>A | 3'UTR (SNP) | VAF 87/157 reads (55%) | called by muse, mutect2, varscan2
- SMOC1 | c.*174T>G | 3'UTR (SNP) | VAF 5/89 reads (6%) | called by muse, mutect2
- SREK1 | chr5:66181094 T>G | 3'Flank (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- SYT4 | c.*390T>G | 3'UTR (SNP) | VAF 62/121 reads (51%) | catalogued as rs1427962569; called by muse, mutect2, varscan2
- SYTL2 | c.2104-52T>G | Intron (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- TAAR3P | n.532G>A | RNA (SNP) | VAF 135/143 reads (94%) | catalogued as rs1376581763; called by muse, mutect2, varscan2
- THYN1 | c.-293A>G | 5'UTR (SNP) | VAF 148/311 reads (48%) | called by muse, mutect2, varscan2
- TMEM70 | c.*204G>C | 3'UTR (SNP) | VAF 61/133 reads (46%) | catalogued as rs1331309677; called by muse, mutect2, varscan2
- TREM2 | chr6:41163175 C>T | 5'Flank (SNP) | VAF 115/270 reads (43%) | called by muse, mutect2, varscan2
- TTI2 | chr8:33513566 T>G | 5'Flank (SNP) | VAF 124/277 reads (45%) | called by muse, mutect2, varscan2
- VAMP1 | c.*1003G>A | 3'UTR (SNP) | VAF 47/139 reads (34%) | called by muse, mutect2, varscan2
- VKORC1L1 | c.*4615T>A | 3'UTR (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- XKR6 | c.*1703A>G | 3'UTR (SNP) | VAF 63/124 reads (51%) | called by muse, mutect2, varscan2
- ZNF579 | c.-2-76C>A | Intron (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2
- ZNF765 | c.*1813G>T | 3'UTR (SNP) | VAF 60/570 reads (11%) | called by muse, mutect2
